Somatic mutation profile of tumor specimen HCM-CSHL-0174-C22-01A (aliquot HCM-CSHL-0174-C22-01A-11D-A78L-36) from HCMI case HCM-CSHL-0174-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 64.9 years (23,717 days).
Specimen HCM-CSHL-0174-C22-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b95c57e5-40f4-4748-a06b-72c7326e6875.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0174-C22-10A (Blood Derived Normal), aliquot HCM-CSHL-0174-C22-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15975a1d-9f38-44c4-96f0-b7b01723b642

The open-access MAF lists 1,460 somatic variants for this specimen: 997 protein-altering or splice-affecting, 275 silent, 188 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 714, Silent 275, Frame Shift Del 174, Intron 98, Nonsense Mutation 33, Frame Shift Ins 33, 3'UTR 29, RNA 25, 5'UTR 24, Splice Site 19, In Frame Del 13, Splice Region 9.

Variants (750 of 1,460; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4615G>A p.E1539K (on ENST00000272895 / NM_173076.3; = p.E1221K on NM_015657.3) | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28940271, CM032168, COSV55968759; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs104894742, CM960074; ClinVar: pathogenic; called by muse, mutect2
- AR | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 62/308 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs137852572, CM136027, CM920086, COSV65954067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.1961del p.K654Sfs*47 | Frame Shift Del (DEL) | VAF 50/246 reads (20%) | catalogued as rs80357522, CD076746, CD951610; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- DYRK1A | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as rs724159949, CM1413207, COSV58294256; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 38/135 reads (28%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GJA1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.768); catalogued as rs2227885, CM014191; ClinVar: likely benign / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 39/151 reads (26%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OTC | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs72554307, CM950870; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 95/277 reads (34%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 52/284 reads (18%) | catalogued as rs121913289; ClinVar: pathogenic; called by pindel, varscan2
- SDHA | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as rs397514541, CM163827, COSV53767867, COSV53772354; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 55/216 reads (25%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 95/266 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912653, CM900212, COSV52764738, COSV52950153; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 33/171 reads (19%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA4 | c.6365C>T p.A2122V | Missense Mutation (SNP) | VAF 123/502 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64671076, COSV64676839; called by muse, mutect2, varscan2
- ABCC10 | c.3835G>A p.V1279M (on ENST00000372530 / NM_001198934.2; = p.V1251M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs762311029; called by muse, mutect2, varscan2
- ABL1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1191034511, COSV59325948; called by muse, mutect2, varscan2
- ABLIM3 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs747716272, COSV58641823; called by muse, mutect2, varscan2
- AC008763.3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 42/203 reads (21%) | catalogued as rs1461187623, COSV100365374; called by muse, mutect2, varscan2
- ACACA | c.5933G>A p.R1978H | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774579864; called by muse, mutect2, varscan2
- ACAN | c.5390G>A p.G1797E | Missense Mutation (SNP) | VAF 109/418 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100719024; called by muse, mutect2, varscan2
- ACAP2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV58753631; called by muse, mutect2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAMTS17 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs993859963; called by muse, mutect2, varscan2
- ADAMTS6 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.41); catalogued as rs143194045; called by muse, mutect2, varscan2
- ADCY1 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338700641, COSV52040140; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRE1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs753846792; called by muse, mutect2, varscan2
- ADGRL1 | c.3419G>A p.R1140H (on ENST00000340736 / NM_001008701.3; = p.R1135H on NM_014921.5) | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs776587952; called by muse, mutect2, varscan2
- AFF2 | c.2513A>G p.Q838R | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as rs1557287421; called by muse, mutect2, varscan2
- AFF2 | c.3110G>A p.S1037N | Missense Mutation (SNP) | VAF 84/421 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.764); catalogued as COSV53979732; called by muse, mutect2, varscan2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 46/170 reads (27%) | catalogued as COSV58317085; called by mutect2, varscan2
- AGBL1 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376945285; called by muse, mutect2, varscan2
- AGGF1 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 33/154 reads (21%) | catalogued as rs758213462, COSV57227705; called by muse, varscan2
- AGO1 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1385910631, COSV64594759; called by muse, mutect2
- AICDA | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs373061990, COSV57563722, COSV57563879; called by muse, mutect2, varscan2
- AL031777.2 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 72/356 reads (20%) | catalogued as rs773584959; called by pindel, varscan2
- ALG10 | c.981dup p.V328Cfs*18 | Frame Shift Ins (INS) | VAF 36/189 reads (19%) | catalogued as rs768493124; called by mutect2, pindel, varscan2
- AMPD2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 73/456 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV56648847; called by muse, mutect2, varscan2
- AMPD3 | c.1686G>A p.M562I (on ENST00000396553 / NM_001025389.2; = p.M571I on NM_000480.3) | Missense Mutation (SNP) | VAF 114/453 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as rs372507080; called by muse, mutect2
- ANK1 | c.5329C>T p.R1777W | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.394); catalogued as rs781061339; called by muse, mutect2
- ANO1 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV60290126; called by muse, mutect2, varscan2
- AP4E1 | c.1064del p.L355* | Frame Shift Del (DEL) | VAF 35/203 reads (17%) | catalogued as rs1357583521; called by mutect2, pindel, varscan2
- APBB1 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1420119374; called by muse, mutect2, varscan2
- APOE | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 106/441 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as CM111115, COSV52985125; called by muse, mutect2, varscan2
- APOOL | c.595del p.T199Lfs*3 | Frame Shift Del (DEL) | VAF 26/124 reads (21%) | catalogued as rs1293508812; called by mutect2, pindel, varscan2
- AQR | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 83/349 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs780179363, COSV99333261; called by muse, mutect2, varscan2
- ARAP1 | c.1514G>A p.R505H (on ENST00000393609 / NM_001040118.2; = p.R260H on NM_015242.4) | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs777692919; called by muse, mutect2, varscan2
- ARHGAP21 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs530533376, COSV57604133; called by muse, mutect2, varscan2
- ARHGEF10L | c.432C>T p.P144= | Splice Region (SNP) | VAF 39/131 reads (30%) | catalogued as rs755364404, COSV63422614; called by muse, mutect2, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | catalogued as COSV61388445; called by mutect2, pindel, varscan2
- ARID1A | c.3820G>T p.G1274* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV61371474; called by muse, mutect2, varscan2
- ARRB2 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV52617001; called by muse, mutect2, varscan2
- ARSD | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.42); catalogued as rs774734859; called by muse, mutect2, varscan2
- ARSI | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60817065, COSV60817994; called by muse, mutect2, varscan2
- ASB11 | c.68dup p.F24Lfs*2 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as rs770804405; called by mutect2, varscan2
- ASTN1 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs745514951, COSV56065176, COSV56066780; called by muse, mutect2
- ASTN1 | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs774847597, COSV99920531; called by muse, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATP2A1 | c.2267_2269del p.N756del | In Frame Del (DEL) | VAF 96/494 reads (19%) | catalogued as rs766141393; called by pindel, varscan2
- ATP4A | c.1292C>A p.A431E | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs375401694; called by muse, mutect2, varscan2
- BAG4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.707); catalogued as rs770041398, COSV54861341, COSV54862630; called by muse, mutect2, varscan2
- BAIAP3 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.135); catalogued as rs770815658; called by muse, mutect2, varscan2
- BAZ1B | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59991019, COSV59993745; called by muse, mutect2, varscan2
- BCL6 | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs1178677766, COSV99216165; called by muse, mutect2, varscan2
- BCL7C | c.617del p.P206Hfs*36 | Frame Shift Del (DEL) | VAF 43/160 reads (27%) | catalogued as rs754078059; called by mutect2, pindel, varscan2
- BCR | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs1244976763; called by muse, mutect2, varscan2
- BEND3 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs147116683; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | catalogued as rs755506199; called by mutect2, varscan2
- BTK | c.215del p.N72Ifs*49 | Frame Shift Del (DEL) | VAF 80/384 reads (21%) | catalogued as CD087030, CD982512, CX984150; called by pindel, varscan2
- C16orf46 | c.412del p.Q138Rfs*66 | Frame Shift Del (DEL) | VAF 36/159 reads (23%) | catalogued as rs1567574033; called by mutect2, pindel, varscan2
- C1QTNF2 | c.218G>A p.R73Q (on ENST00000393975; = p.R28Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs375483575; called by muse, mutect2, varscan2
- C21orf58 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs375276205; called by muse, mutect2, varscan2
- C2CD5 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 77/298 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.073); catalogued as rs151297499; called by muse, mutect2, varscan2
- CACNA1E | c.2705del p.G902Efs*5 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as COSV62382319; called by mutect2, pindel, varscan2
- CAGE1 | c.2238del p.A747Pfs*9 (on ENST00000512086; = p.A611Pfs*9 on NM_205864.3) | Frame Shift Del (DEL) | VAF 29/151 reads (19%) | catalogued as COSV57081154; called by mutect2, pindel, varscan2
- CAMK1G | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs763192311; called by muse, mutect2, varscan2
- CAMSAP3 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as rs185048709; called by muse, mutect2, varscan2
- CAPG | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs756006551, COSV99809333; called by muse, mutect2, varscan2
- CARM1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV53404227; called by muse, mutect2, varscan2
- CARMIL1 | c.3244C>T p.R1082* | Nonsense Mutation (SNP) | VAF 60/229 reads (26%) | catalogued as rs1385108756, COSV61523112; called by muse, mutect2, varscan2
- CBARP | c.1067G>T p.R356L (on ENST00000382477; = p.R336L on NM_152769.3) | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53071806; called by muse, mutect2, varscan2
- CCDC136 | c.2066A>G p.Q689R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99923222; called by muse, mutect2
- CCDC168 | c.8926G>A p.A2976T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV59426418; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC38 | c.355A>G p.R119G | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs145671956; called by muse, mutect2, varscan2
- CCN4 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs778202911, COSV51533217; called by muse, mutect2, varscan2
- CCNJ | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as rs1488931381, COSV99796155; called by muse, mutect2, varscan2
- CCT7 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs11544996; called by muse, mutect2, varscan2
- CD3E | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 101/457 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.123); catalogued as rs200087808; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD3E | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 87/372 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs563868055, COSV62346096; called by muse, mutect2, varscan2
- CD93 | c.1307del p.G436Afs*152 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as rs779465056; called by mutect2, pindel, varscan2
- CDADC1 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.181); catalogued as rs149569821; called by muse, mutect2, varscan2
- CDH22 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs1303483268, COSV64837485; called by muse, mutect2, varscan2
- CDK13 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs934764468, COSV51706512; called by muse, mutect2
- CDYL | c.1192G>A p.V398I (on ENST00000328908 / NM_001368125.1; = p.V344I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs761722419, COSV59361810; called by muse, mutect2, varscan2
- CEP97 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs145086802; called by muse, mutect2, varscan2
- CERS6 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV59830504; called by muse, mutect2, varscan2
- CES5A | c.1005T>G p.I335M | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs866504798; called by muse, mutect2, varscan2
- CFAP43 | c.4579dup p.S1527Ffs*10 | Frame Shift Ins (INS) | VAF 26/87 reads (30%) | catalogued as rs775645707; called by mutect2, varscan2
- CFAP94 | c.1798G>A p.A600T (on ENST00000320267 / NM_001352064.2; = p.A606T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57230325; called by muse, mutect2, varscan2
- CGB5 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 39/603 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1201663825; called by muse, mutect2, varscan2
- CHD5 | c.5660del p.P1887Rfs*14 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | catalogued as rs928253921; called by mutect2, varscan2
- CHPF | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs776863694, COSV60537310; called by muse, mutect2, varscan2
- CHRM4 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs759941649, COSV63126375; called by muse, mutect2, varscan2
- CHRNA6 | c.494del p.F165Sfs*10 | Frame Shift Del (DEL) | VAF 30/156 reads (19%) | catalogued as rs774808608; called by mutect2, pindel, varscan2
- CLASP2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.114); catalogued as rs368159421; called by muse, mutect2, varscan2
- CLEC16A | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.065); catalogued as rs866629699; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | catalogued as rs369752219; called by mutect2, varscan2
- CMIP | c.1555C>G p.R519G (on ENST00000537098 / NM_198390.2; = p.R425G on NM_030629.3) | Missense Mutation (SNP) | VAF 92/473 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67698609; called by muse, mutect2, varscan2
- CNGA2 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756195328, COSV100323969; called by muse, mutect2, varscan2
- CNNM1 | c.2176+1G>A p.X726_splice | Splice Site (SNP) | VAF 44/206 reads (21%) | catalogued as rs376631525; called by muse, mutect2, varscan2
- COL20A1 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as rs748113437, COSV58914315; called by muse, mutect2, varscan2
- COL6A3 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs753966526, COSV55104699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV53731656; called by muse, mutect2, varscan2
- CORO6 | c.1194del p.K399Sfs*96 | Frame Shift Del (DEL) | VAF 48/221 reads (22%) | catalogued as rs756429595; called by mutect2, pindel, varscan2
- CRNKL1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781077783, COSV99842955; called by muse, mutect2, varscan2
- CSPP1 | c.1102C>T p.P368S (on ENST00000676605; = p.P327S on NM_024790.6) | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV51580378; called by muse, mutect2, varscan2
- CT47B1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 119/520 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746190277, COSV100989010; called by muse, mutect2, varscan2
- CTBP1 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 52/455 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1388198458; called by muse, mutect2, varscan2
- CTNNA1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 72/189 reads (38%) | catalogued as COSV57077911; called by muse, mutect2, varscan2
- CWH43 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs1415857655, COSV99893165; called by muse, mutect2, varscan2
- CYBRD1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs150572307; called by muse, mutect2
- CYP2C8 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1313975039; called by muse, mutect2
- CYP2C9 | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV53247604; called by muse, mutect2, varscan2
- CYS1 | c.475T>G p.*159Gext*29 | Nonstop Mutation (SNP) | VAF 45/145 reads (31%) | catalogued as rs774180325; called by muse, mutect2, varscan2
- DAPK2 | c.1033-7del | Splice Region (DEL) | VAF 12/62 reads (19%) | catalogued as rs753638020; called by mutect2, varscan2
- DENND1B | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs779126393; called by muse, mutect2, varscan2
- DEPDC5 | c.2968G>A p.A990T (on ENST00000400246; = p.A1059T on NM_014662.5) | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.153); catalogued as rs763158282, COSV99835501; called by muse, mutect2, varscan2
- DICER1 | c.3791C>T p.T1264M | Missense Mutation (SNP) | VAF 57/471 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs139346443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIP2A | c.3706G>A p.V1236I | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs761203268, COSV59481294; called by muse, mutect2, varscan2
- DIP2C | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as rs775934914, COSV99792008; called by muse, varscan2
- DLL4 | c.2053G>A p.V685I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1404800749, COSV99990087; called by muse, mutect2, varscan2
- DLST | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1025995190, COSV53168045; called by muse, mutect2, varscan2
- DNAH10 | c.3172C>T p.R1058* (on ENST00000409039; = p.R997* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 46/178 reads (26%) | catalogued as rs1449530904, COSV68991805; called by muse, mutect2, varscan2
- DNAJC10 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as rs768125706; called by muse, mutect2, varscan2
- DNHD1 | c.10298G>A p.R3433H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1182015408; called by muse, mutect2
- DNMT3B | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 14/506 reads (3%) | catalogued as CM164014, COSV52417440; called by muse, mutect2
- DOCK8 | c.5059G>A p.V1687M | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs767895149, COSV101209866; called by muse, mutect2, varscan2
- DOCK9 | c.3526G>A p.V1176I (on ENST00000376460 / NM_001366676.2; = p.V1177I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as rs1471236386, COSV59643438; called by muse, mutect2
- DPF2 | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV52891484; called by muse, mutect2, varscan2
- DSCAML1 | c.754G>A p.A252T (on ENST00000321322; = p.A192T on NM_020693.4) | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs142110596, COSV58389573; called by muse, mutect2, varscan2
- DVL1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs149964617; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- ECT2 | c.2507del p.K836Rfs*21 (on ENST00000392692 / NM_001349098.2; = p.K805Rfs*21 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | catalogued as rs1560030630; called by mutect2, pindel, varscan2
- EIF3CL | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV66534056; called by muse, mutect2, varscan2
- EIF4A3 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs755596816; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | catalogued as rs770453803; called by mutect2, varscan2
- EP400 | c.6545C>T p.A2182V | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs565827189; called by muse, varscan2
- EPRS1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448727059; called by muse, mutect2, varscan2
- ERBIN | c.3389G>A p.R1130Q | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144581883; called by muse, mutect2, varscan2
- ERICH3 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs865943394, COSV58604950; called by muse, mutect2, varscan2
- FAF2 | c.484-1G>T p.X162_splice | Splice Site (SNP) | VAF 23/83 reads (28%) | catalogued as COSV99990456; called by muse, mutect2, varscan2
- FAM184A | c.2854C>T p.R952W | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs775749960; called by muse, mutect2, varscan2
- FAM3D | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs368973392; called by muse, mutect2, varscan2
- FAM83D | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 87/322 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757902095; called by muse, mutect2, varscan2
- FAM91A1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1012721253, COSV58236363; called by muse, mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as rs757443519; called by mutect2, varscan2
- FASN | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs1009899437; called by muse, mutect2, varscan2
- FASTKD1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs149861551; called by muse, mutect2, varscan2
- FAT4 | c.14389C>T p.L4797F | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs267600018, COSV58703970; called by muse, mutect2, varscan2
- FGD2 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780657307, COSV51464056; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/131 reads (23%) | catalogued as COSV58769165; called by mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FKRP | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764621521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNA | c.2836G>T p.G946C | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV61051609; called by muse, mutect2, varscan2
- FLNC | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 106/389 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1417082178, COSV57949813; called by muse, mutect2, varscan2
- FLOT2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774018833; called by muse, mutect2, varscan2
- FLT3 | c.2729A>G p.Q910R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.021); catalogued as rs1318196723; called by muse, mutect2, varscan2
- FLYWCH1 | c.1907G>A p.R636Q (on ENST00000253928 / NM_001308068.2; = p.R635Q on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs777293183; called by muse, mutect2, varscan2
- FNIP2 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1314321471, COSV52439130; called by muse, mutect2, varscan2
- FOXC1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 193/757 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXH1 | c.937del p.V313Wfs*15 | Frame Shift Del (DEL) | VAF 88/432 reads (20%) | catalogued as COSV56761013; called by mutect2, pindel, varscan2
- FRZB | c.855del p.V286Lfs*6 | Frame Shift Del (DEL) | VAF 46/186 reads (25%) | catalogued as rs1366062663; called by mutect2, pindel, varscan2
- G6PD | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 115/506 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as CM920286, COSV63703327; called by muse, mutect2, varscan2
- GABPB2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 27/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770162643, COSV104425990; called by muse, mutect2, varscan2
- GALNT3 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as rs376963628; called by muse, mutect2, varscan2
- GGTLC1 | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 186/837 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs541165436, COSV99600652; called by muse, mutect2, varscan2
- GIGYF1 | c.331dup p.L111Pfs*20 | Frame Shift Ins (INS) | VAF 30/128 reads (23%) | catalogued as rs763147690; called by mutect2, varscan2
- GIT1 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs769808064; called by muse, mutect2, varscan2
- GNB3 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV51831647; called by muse, mutect2, varscan2
- GNE | c.623G>A p.R208H (on ENST00000396594 / NM_001128227.3; = p.R177H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs772597073, COSV64951377; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GNPAT | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 100/436 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs767959114, COSV64152975; called by muse, mutect2, varscan2
- GP5 | c.1403del p.G468Vfs*43 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs750921214; called by mutect2, pindel, varscan2
- GPKOW | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs782735883; called by muse, mutect2, varscan2
- GPR108 | c.1018G>A p.A340T (on ENST00000264080 / NM_001080452.1; = p.A98T on NM_020171.2) | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs371747238; called by muse, mutect2, varscan2
- GPR179 | c.4108G>A p.E1370K (on ENST00000621958; = p.E1369K on NM_001004334.4) | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs11872089; called by muse, mutect2, varscan2
- GRK2 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs752975715; called by muse, mutect2, varscan2
- HERC1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs769145958, COSV71250686; called by muse, mutect2, varscan2
- HERC4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1164946098, COSV53268584; called by muse, mutect2, varscan2
- HIRA | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54277074; called by muse, mutect2, varscan2
- HIRIP3 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs139557944; called by muse, mutect2, varscan2
- HIVEP2 | c.4556C>T p.S1519L | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs764073074; called by muse, mutect2, varscan2
- HIVEP2 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 30/131 reads (23%) | catalogued as COSV50007394; called by muse, varscan2
- HNF4G | c.224C>T p.A75V (on ENST00000354370 / NM_001330561.2; = p.A122V on NM_004133.5) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as rs770285159, COSV62972179; called by muse, mutect2, varscan2
- HRC | c.1269del p.R424Gfs*38 | Frame Shift Del (DEL) | VAF 47/181 reads (26%) | catalogued as COSV53255991; called by mutect2, varscan2
- HSPA1L | c.1314del p.V440Cfs*2 | Frame Shift Del (DEL) | VAF 75/341 reads (22%) | catalogued as COSV65149080; called by mutect2, pindel, varscan2
- HSPG2 | c.8212G>A p.V2738M | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144862631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPG2 | c.1858T>C p.Y620H | Missense Mutation (SNP) | VAF 104/731 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs928196274; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 41/166 reads (25%) | catalogued as rs747841314; called by mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 59/288 reads (20%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGHV3-16 | c.105dup p.S36Vfs*15 | Frame Shift Ins (INS) | VAF 136/417 reads (33%) | catalogued as rs782240233; called by mutect2, pindel, varscan2
- IGHV4-39 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 219/532 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs587685263; called by muse, varscan2
- IGKV1-17 | c.345T>G p.S115R | Missense Mutation (SNP) | VAF 102/457 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1435944291; called by muse, mutect2, varscan2
- IMPDH1 | c.608G>A p.S203N (on ENST00000470772 / NM_001142573.2; = p.S289N on NM_000883.4) | Missense Mutation (SNP) | VAF 126/539 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV100118624; called by muse, mutect2, varscan2
- INPPL1 | c.3425G>A p.R1142H | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779810240; called by muse, mutect2, varscan2
- INTS1 | c.3478G>T p.A1160S | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV101247519; called by muse, mutect2, varscan2
- INTS1 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV67179428; called by muse, mutect2, varscan2
- INTS8 | c.2954del p.K985Sfs*44 | Frame Shift Del (DEL) | VAF 35/195 reads (18%) | catalogued as rs1352150703; called by mutect2, varscan2
- INVS | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 119/335 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs529208660; called by muse, mutect2, varscan2
- IQCE | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.469); catalogued as rs201141275; called by muse, mutect2, varscan2
- IRF7 | c.212G>A p.R71H (on ENST00000397566; = p.R58H on NM_001572.5) | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs766334448; called by muse, mutect2, varscan2
- IRGC | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54983350; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as rs761880048; called by mutect2, varscan2
- IRX2 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.019); catalogued as rs796424759; called by muse, mutect2, varscan2
- ISG15 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 123/390 reads (32%) | catalogued as rs200652935; called by muse, mutect2, varscan2
- ISLR2 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as rs1198523188; called by muse, mutect2, varscan2
- ISLR2 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.41); catalogued as COSV62303721; called by muse, mutect2, varscan2
- ITGAL | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs750373265, COSV63322312; called by muse, mutect2, varscan2
- ITGB7 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); catalogued as rs1356768179; called by muse, mutect2, varscan2
- ITIH6 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs750304500, COSV54488247; called by muse, mutect2, varscan2
- JAM3 | c.745dup p.V249Gfs*28 | Frame Shift Ins (INS) | VAF 100/456 reads (22%) | catalogued as rs763250381; called by mutect2, varscan2
- KCNA1 | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 99/518 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM940994; called by muse, varscan2
- KCNG4 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753628017; called by muse, mutect2, varscan2
- KCNH3 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs201670637; called by muse, mutect2, varscan2
- KCNK2 | c.817G>A p.V273I (on ENST00000444842 / NM_001017425.3; = p.V258I on NM_014217.4) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs367815630; called by muse, mutect2, varscan2
- KCTD18 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs543025211, COSV63344171; called by muse, mutect2, varscan2
- KCTD18 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1243082924, COSV63344199; called by muse, mutect2, varscan2
- KCTD21 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs778118017, COSV60741135, COSV60741494, COSV60741878; called by muse, mutect2, varscan2
- KIAA0319L | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs770305152, COSV57848683; called by muse, mutect2, varscan2
- KIAA1671 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as rs1271381341; called by muse, varscan2
- KIAA2026 | c.4717G>A p.V1573M | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101198947; called by muse, mutect2, varscan2
- KIF18B | c.1178del p.G393Efs*91 (on ENST00000593135 / NM_001265577.2; = p.G393Efs*103 on NM_001264573.2) | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | catalogued as rs1347932473, COSV59271974, COSV59272099; called by mutect2, pindel, varscan2
- KIF1A | c.2344del p.R782Afs*30 | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | catalogued as COSV57494105, COSV57504132; called by mutect2, pindel, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 70/257 reads (27%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLF1 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs886054237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL20 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1337434730, COSV52940996; called by muse, mutect2, varscan2
- KLHL22 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1273833949, COSV61020365; called by muse, mutect2
- KLHL40 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187688307, COSV99825551; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.6895del p.R2299Gfs*26 | Frame Shift Del (DEL) | VAF 33/152 reads (22%) | catalogued as rs1568382485; called by mutect2, pindel, varscan2
- KMT2C | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs150747860; ClinVar: not provided; called by muse, mutect2, varscan2
- KNDC1 | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs566345817, COSV58831384; called by muse, mutect2, varscan2
- KPNA2 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs369989302; called by muse, mutect2
- KRI1 | c.666G>A p.T222= | Splice Region (SNP) | VAF 24/72 reads (33%) | catalogued as rs776247947, COSV100469631; called by muse, mutect2
- KRTAP2-1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as rs1435605987; called by muse, mutect2, varscan2
- KSR1 | c.437C>T p.T146M (on ENST00000644974 / NM_001367810.1; = p.T9M on NM_014238.2) | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.137); catalogued as rs761371576; called by muse, mutect2, varscan2
- L3MBTL4 | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV53123806; called by muse, mutect2, varscan2
- LAPTM4B | c.750_752del p.L251del (on ENST00000445593; = p.L160del on NM_018407.6) | In Frame Del (DEL) | VAF 16/134 reads (12%) | catalogued as rs777944332; called by pindel, varscan2
- LAPTM5 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs762845113, COSV99612501; called by muse, mutect2
- LDLRAD4 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324351524; called by muse, mutect2
- LPCAT2 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV50896497; called by muse, mutect2, varscan2
- LPCAT3 | c.1348-2A>G p.X450_splice | Splice Site (SNP) | VAF 14/71 reads (20%) | catalogued as rs1443920755; called by muse, mutect2, varscan2
- LRP1 | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54520303; called by muse, varscan2
- LRRTM3 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.088); catalogued as COSV63669719; called by muse, mutect2, varscan2
- LUZP2 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV61208270; called by muse, mutect2, varscan2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as rs758700583; called by mutect2, pindel, varscan2
- MAP3K15 | c.3851G>A p.R1284Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100135161; called by muse, mutect2, varscan2
- MAPK14 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57696494; called by muse, mutect2, varscan2
- MAPT | c.1202C>T p.A401V (on ENST00000262410 / NM_001377265.1; = p.A326V on NM_016835.4) | Missense Mutation (SNP) | VAF 66/267 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV52239842; called by muse, mutect2, varscan2
- MARK2 | c.1582C>T p.R528C (on ENST00000402010 / NM_001039469.2; = p.R494C on NM_017490.4) | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs972173237, COSV59282370; called by muse, mutect2, varscan2
- MAST1 | c.3196C>A p.R1066S | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52243316; called by muse, mutect2, varscan2
- MAST4 | c.6599C>T p.P2200L (on ENST00000403625 / NM_001164664.2; = p.P2011L on NM_015183.3) | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs986498579, COSV104375397; called by muse, mutect2, varscan2
- MBNL1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 101/403 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.203); catalogued as rs780538995, COSV56828467, COSV56836247; called by muse, mutect2, varscan2
- MBTD1 | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64504345; called by muse, mutect2, varscan2
- MCF2L | c.2198G>A p.R733H (on ENST00000375608; = p.R701H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs774936427, COSV56175265; called by muse, mutect2, varscan2
- MCFD2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 120/532 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.204); catalogued as rs1162286700, COSV60177920; called by muse, mutect2, varscan2
- MCTP2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as rs571941802, COSV59144810; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MED13L | c.5585A>G p.N1862S | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1397464926; called by muse, mutect2, varscan2
- MEF2B | c.542-2A>G p.X181_splice | Splice Site (SNP) | VAF 24/98 reads (24%) | catalogued as COSV50766234; called by muse, mutect2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | catalogued as rs762115034; called by mutect2, varscan2
- MICAL2 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.044); catalogued as rs763464953, COSV56319816; called by muse, mutect2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MMP25 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs143925847, COSV60678875; called by muse, mutect2, varscan2
- MORN1 | c.747C>T p.S249= | Splice Region (SNP) | VAF 29/148 reads (20%) | catalogued as rs751372454, COSV101047542; called by muse, mutect2, varscan2
- MPO | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 127/470 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761949874, COSV56561209; called by muse, mutect2, varscan2
- MRC2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs546895407, COSV57636441; called by muse, mutect2, varscan2
- MRE11 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs767097795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRM2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54247956; called by muse, mutect2, varscan2
- MROH8 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs769537714, COSV54117943; called by muse, mutect2
- MRPS11 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs762797699; called by muse, mutect2, varscan2
- MUC16 | c.34094C>T p.T11365I | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs777642205; called by muse, mutect2, varscan2
- MUC17 | c.1025G>A p.S342N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1164758470; called by muse, mutect2, varscan2
- MUC17 | c.5107G>C p.A1703P | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV60301305; called by muse, mutect2, varscan2
- MVK | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 159/605 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs372166675; called by muse, varscan2
- MYOG | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.277); catalogued as rs200354483, COSV54095180; called by muse, varscan2
- MYOM3 | c.4207G>T p.G1403C | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773501383, COSV58391370, COSV58399053; called by muse, mutect2, varscan2
- NCAPG2 | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs527840789; called by muse, mutect2, varscan2
- NDUFA7 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as COSV56847732; called by muse, mutect2, varscan2
- NET1 | c.941G>A p.R314H (on ENST00000355029 / NM_001047160.3; = p.R260H on NM_005863.5) | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1205204380; called by muse, mutect2, varscan2
- NEXMIF | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50025295; called by muse, mutect2, varscan2
- NIBAN2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs762563150, COSV64825334; called by muse, mutect2, varscan2
- NIPBL | c.7801A>G p.M2601V | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs759275114; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | catalogued as rs763440516; called by mutect2, varscan2
- NKX1-1 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs1469500275; called by muse, mutect2, varscan2
- NOC4L | c.907del p.X303_splice | Splice Site (DEL) | VAF 14/75 reads (19%) | catalogued as rs765400964; called by mutect2, pindel, varscan2
- NOLC1 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs141424326; called by muse, mutect2, varscan2
- NR4A3 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV58243212; called by muse, mutect2, varscan2
- NT5DC3 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs758485823; called by muse, mutect2, varscan2
- NTRK3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs201426743, COSV58111825; called by muse, mutect2, varscan2
- NTSR1 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368494260; called by muse, mutect2, varscan2
- NUMBL | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.755); catalogued as rs1192526014; called by muse, mutect2, varscan2
- OBSL1 | c.4583G>A p.R1528H | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759240898, COSV54705958; called by muse, mutect2, varscan2
- OLA1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375033952, COSV52969227; called by muse, mutect2, varscan2
- OPLAH | c.3221C>T p.A1074V | Missense Mutation (SNP) | VAF 94/434 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1554757941, COSV70677818; called by muse, mutect2, varscan2
- OR10H3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs778942345, COSV59943941; called by muse, mutect2, varscan2
- OR10T2 | c.518A>T p.N173I | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57780033; called by muse, mutect2, varscan2
- OR1C1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 57/326 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs372819870, COSV101376227; called by muse, mutect2, varscan2
- OR2A4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59575638; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 39/248 reads (16%) | catalogued as rs1268396241; called by mutect2, pindel, varscan2
- OR51E1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.699); catalogued as rs370898634, COSV67809759; called by muse, mutect2, varscan2
- OR51E1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200993659, COSV67810326; called by muse, mutect2, varscan2
- OR5H2 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV100788702, COSV62350300; called by muse, mutect2, varscan2
- P4HA2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs147398523, COSV51324938; called by muse, mutect2, varscan2
- PCDH10 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52099108, COSV99993103; called by muse, varscan2
- PCDHGA6 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 10/328 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1415388106, COSV53989482; called by muse, mutect2
- PCDHGA9 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs199517824; called by muse, mutect2, varscan2
- PDE6B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs182545478; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 56/244 reads (23%) | catalogued as rs747131399; called by mutect2, varscan2
- PER1 | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs753045671; called by muse, mutect2, varscan2
- PGAM5 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs144537165; called by muse, mutect2
- PGLS | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 114/461 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1381699018; called by muse, mutect2, varscan2
- PIGO | c.1361del p.G454Vfs*31 | Frame Shift Del (DEL) | VAF 72/254 reads (28%) | catalogued as COSV53054111, COSV53054694; called by mutect2, pindel, varscan2
- PIP5K1C | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs377291771, COSV58950241; called by muse, mutect2, varscan2
- PIPOX | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756943831; called by muse, mutect2
- PLD3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 59/383 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1246045495; called by mutect2, varscan2
- PLD5 | c.1121G>A p.R374Q (on ENST00000442594; = p.R312Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV59163972; called by muse, mutect2, varscan2
- PLEKHM3 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as rs1416993669, COSV66815589; called by muse, mutect2, varscan2
- PLXNB3 | c.5320C>T p.R1774W | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs139661833; called by muse, mutect2
- POLE | c.4477G>A p.A1493T | Missense Mutation (SNP) | VAF 85/391 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs748522633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPEF2 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99714719; called by muse, mutect2
- PPP2R3B | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs760244257, COSV66813342; called by muse, mutect2, varscan2
- PPP3CA | c.230del p.N77Ifs*22 | Frame Shift Del (DEL) | VAF 31/126 reads (25%) | catalogued as rs1250808026; called by mutect2, varscan2
- PPP5C | c.46dup p.R16Pfs*7 | Frame Shift Ins (INS) | VAF 66/272 reads (24%) | catalogued as rs766639242; called by mutect2, varscan2
- PRB4 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 48/570 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.036); catalogued as COSV54398610; called by muse, mutect2
- PRDM16 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1407647352, COSV54605049, COSV54606419; called by muse, mutect2, varscan2
- PRDM9 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs112157044; called by muse, mutect2, varscan2
- PRG4 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 122/528 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as rs369769286, COSV66624843; called by muse, mutect2, varscan2
- PRKDC | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs772980444; called by muse, mutect2, varscan2
- PRKX | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1348033937; called by muse, mutect2, varscan2
- PROS1 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs373336653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PROX1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1374775160, COSV99800417; called by muse, mutect2, varscan2
- PRPF3 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs201590000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR5 | c.494C>T p.A165V (on ENST00000336985 / NM_181333.4; = p.A156V on NM_015366.4) | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs572406576; called by muse, mutect2, varscan2
- PRSS38 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs373887552; called by muse, mutect2, varscan2
- PUM2 | c.3038C>T p.A1013V | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV57584191; called by muse, mutect2
- PUM2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV100163837, COSV57580987; called by muse, mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 62/282 reads (22%) | catalogued as rs768997455; called by mutect2, varscan2
- PWWP2B | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs965289685; called by muse, mutect2, varscan2
- PYHIN1 | c.1048del p.T350Qfs*6 | Frame Shift Del (DEL) | VAF 14/83 reads (17%) | catalogued as COSV63722536; called by mutect2, pindel, varscan2
- RAB11FIP1 | c.37del p.A13Pfs*10 | Frame Shift Del (DEL) | VAF 42/180 reads (23%) | catalogued as rs35243840; called by mutect2, varscan2
- RANBP2 | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 84/428 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs978251652; called by muse, mutect2, varscan2
- RASGRP2 | c.1479dup p.R494Afs*54 | Frame Shift Ins (INS) | VAF 73/248 reads (29%) | catalogued as rs774996406; called by mutect2, varscan2
- RASGRP4 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 43/175 reads (25%) | catalogued as rs766578361, COSV99498370; called by muse, mutect2, varscan2
- RBFA | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs139845183; called by muse, mutect2, varscan2
- RBM10 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 103/524 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs868977796; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBMXL1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs374309282; called by muse, mutect2, varscan2
- RBMXL3 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1385235583; called by muse, mutect2, varscan2
- REPIN1 | c.1116dup p.S373Lfs*228 | Frame Shift Ins (INS) | VAF 22/97 reads (23%) | catalogued as rs759247453; called by mutect2, varscan2
- REPIN1 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1213016608; called by muse, mutect2, varscan2
- RILPL1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1246793683; called by muse, mutect2, varscan2
- RNF213 | c.12949C>T p.R4317W | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs759256018, COSV60407022; called by muse, mutect2, varscan2
- ROS1 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs771282907; called by muse, mutect2, varscan2
- RP1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 89/349 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369804244, COSV55114432; called by muse, mutect2, varscan2
- RP1 | c.2572del p.I858Yfs*37 | Frame Shift Del (DEL) | VAF 35/172 reads (20%) | catalogued as rs1214953601; called by mutect2, pindel, varscan2
- RP1L1 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs1187441272, COSV66754347; called by muse, mutect2, varscan2
- RPP30 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.818); catalogued as rs137907824; called by muse, mutect2, varscan2
- RPRD2 | c.4048G>T p.G1350W | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV64818724; called by muse, mutect2, varscan2
- RRM1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56162867; called by muse, mutect2, varscan2
- RRP1 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 98/373 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs749236769; called by muse, varscan2
- RSPH10B | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs749914563; called by mutect2, varscan2
- RXFP1 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 76/326 reads (23%) | catalogued as rs200071060, COSV57055994; called by muse, mutect2, varscan2
- RYR1 | c.2079del p.Y694Tfs*36 | Frame Shift Del (DEL) | VAF 57/274 reads (21%) | catalogued as rs1568451501; called by mutect2, pindel, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 125/486 reads (26%) | catalogued as rs753320334; called by mutect2, varscan2
- SCAF4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs1439594249, COSV54584476, COSV54585696; called by muse, mutect2, varscan2
- SCARF1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs867533840, COSV53958347, COSV53961566; called by muse, mutect2, varscan2
- SDK1 | c.5350G>A p.A1784T | Missense Mutation (SNP) | VAF 117/489 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761076885, COSV67355271; called by muse, mutect2, varscan2
- SERTAD2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs772856400, COSV57641417; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs1260834379; called by mutect2, varscan2
- SH3BP1 | c.1735del p.Q579Rfs*79 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as rs70950549; called by mutect2, pindel, varscan2
- SH3BP5L | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as rs759575065; called by muse, mutect2, varscan2
- SH3RF3 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1451660266; called by muse, mutect2
- SHANK1 | c.4354G>A p.A1452T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1469441882; called by muse, mutect2, varscan2
- SHANK3 | c.4504C>T p.R1502C | Missense Mutation (SNP) | VAF 88/435 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs575384100; called by muse, mutect2, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 20/144 reads (14%) | catalogued as rs1469942319; called by mutect2, varscan2
- SHROOM3 | c.3193G>A p.G1065S | Missense Mutation (SNP) | VAF 137/561 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.453); catalogued as rs775439655; called by muse, mutect2, varscan2
- SIAH3 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs750047881, COSV68552598; called by muse, mutect2, varscan2
- SKOR2 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV68550018; called by muse, mutect2, varscan2
- SLC15A1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs764483622, COSV64732066; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 87/335 reads (26%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC16A6 | c.294dup p.L99Afs*34 | Frame Shift Ins (INS) | VAF 38/182 reads (21%) | catalogued as rs782184620; called by mutect2, varscan2
- SLC27A3 | c.1636C>T p.P546S (on ENST00000271857; = p.P418S on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs1303528906; called by muse, mutect2, varscan2
- SLC2A7 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs773308377, COSV68901454; called by muse, varscan2
- SLC49A3 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs747020127, COSV59141639; called by muse, mutect2, varscan2
- SLC5A10 | c.1213G>A p.G405S (on ENST00000395645 / NM_001042450.4; = p.G421S on NM_152351.5) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs780119794; called by muse, mutect2, varscan2
- SLC5A11 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs368113331; called by muse, mutect2, varscan2
- SLC9C1 | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1454329029; called by muse, mutect2, varscan2
- SLITRK6 | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs762216866, COSV101233227; called by muse, mutect2, varscan2
- SNTA1 | c.583del p.L195Ffs*23 | Frame Shift Del (DEL) | VAF 63/320 reads (20%) | catalogued as rs1443071118; called by mutect2, pindel, varscan2
- SNTB2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 112/438 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs758452589; called by muse, varscan2
- SOGA3 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775544839, COSV64106238; called by muse, mutect2, varscan2
- SORBS2 | c.2506C>T p.R836C (on ENST00000284776 / NM_021069.5; = p.R402C on NM_003603.6) | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs756993379; called by muse, mutect2, varscan2
- SORCS1 | c.558+2del p.X186_splice | Splice Site (DEL) | VAF 12/62 reads (19%) | catalogued as COSV53901348; called by mutect2, pindel
- SOS2 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as COSV53566519; called by muse, mutect2, varscan2
- SOX10 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV100329862; called by muse, mutect2, varscan2
- SP5 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs767878015; called by muse, mutect2, varscan2
- SPARCL1 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56805981; called by muse, mutect2, varscan2
- SPDEF | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775855317; called by muse, mutect2, varscan2
- SPHK2 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs760049391; called by muse, mutect2, varscan2
- SPHKAP | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV60869857; called by muse, mutect2, varscan2
- SRC | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62440190; called by muse, mutect2, varscan2
- SREK1IP1 | c.407del p.K136Rfs*22 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs772485731; called by mutect2, pindel, varscan2
- SRGAP1 | c.1565T>C p.I522T | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs202173847; called by muse, mutect2, varscan2
- SRP68 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1222515803; called by muse, mutect2, varscan2
- ST3GAL6 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as COSV54585976; called by muse, mutect2, varscan2
- STIM2 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs201149830, COSV99402981; called by muse, mutect2, varscan2
- STRIP1 | c.1705C>A p.R569S | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874020; called by muse, mutect2, varscan2
- SUGCT | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781200920, COSV59343951; called by muse, mutect2, varscan2
- SUPT6H | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs775521641; called by muse, mutect2, varscan2
- SYCP2L | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs370377149; called by muse, mutect2, varscan2
- SYNGAP1 | c.3929C>T p.T1310M | Missense Mutation (SNP) | VAF 93/338 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs796430835, COSV99538062; called by muse, mutect2, varscan2
- TAOK2 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779224250; called by muse, mutect2, varscan2
- TAS1R1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as rs530483330; called by muse, mutect2, varscan2
- TAS2R9 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as rs756576629, COSV53688628; called by muse, mutect2, varscan2
- TBC1D17 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV55581042; called by muse, mutect2, varscan2
- TBXAS1 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 115/473 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs78666490, COSV54946635; called by muse, mutect2, varscan2
- TCHH | c.3069dup p.D1024Rfs*194 | Frame Shift Ins (INS) | VAF 74/272 reads (27%) | catalogued as rs1298090051; called by mutect2, pindel, varscan2
- TCHHL1 | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV64285813; called by muse, mutect2, varscan2
- TDRD12 | c.3378del p.Q1127Rfs*47 (on ENST00000444215; = p.Q1132Rfs*57 on NM_001366102.1) | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | catalogued as rs1331884293; called by mutect2, pindel
- TDRD5 | c.2783C>T p.S928F | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99675208; called by muse, mutect2, varscan2
- TEX43 | c.241_242del p.L81Vfs*6 | Frame Shift Del (DEL) | VAF 19/151 reads (13%) | catalogued as rs779521055; called by pindel, varscan2
- TFDP3 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.556); catalogued as rs777030815, COSV59536621; called by muse, mutect2, varscan2
- TFPI2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as rs778950207; called by muse, mutect2, varscan2
- THBS3 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772718514, COSV64248425; called by muse, mutect2
- THSD7B | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs370266523; called by muse, mutect2, varscan2
- TIAM1 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs758452455, COSV54542399; called by muse, mutect2, varscan2
- TIPARP | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs150068199; called by muse, mutect2, varscan2
- TLE2 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs776121050; called by muse, mutect2, varscan2
- TLK2 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 22/127 reads (17%) | catalogued as rs779826427; called by pindel, varscan2
- TLL1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99286821; called by muse, mutect2, varscan2
- TMCC2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 119/479 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.749); catalogued as rs1182470181; called by muse, mutect2, varscan2
- TMEM130 | c.804-1G>A p.X268_splice | Splice Site (SNP) | VAF 18/68 reads (26%) | catalogued as rs782243837; called by muse, mutect2, varscan2
- TMEM151A | c.1173dup p.A392Rfs*53 | Frame Shift Ins (INS) | VAF 41/206 reads (20%) | catalogued as rs1158034577; called by mutect2, pindel, varscan2
- TMEM201 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs928354065, COSV61160846; called by muse, mutect2, varscan2
- TMEM54 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368310171; called by muse, mutect2
- TMPRSS9 | c.2800C>T p.R934C (on ENST00000648592; = p.R900C on NM_182973.2) | Missense Mutation (SNP) | VAF 110/413 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs760660660, COSV53115519; called by muse, mutect2, varscan2
- TNFSF12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs758038102, COSV53434011; called by muse, mutect2, varscan2
- TNIP2 | c.657C>T p.H219= | Splice Region (SNP) | VAF 22/129 reads (17%) | catalogued as rs758835523; called by muse, mutect2, varscan2
- TNIP2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 93/361 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs201862092, COSV59569770; called by muse, mutect2, varscan2
- TNPO2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs369773308; called by muse, mutect2, varscan2
- TP53I11 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs762010357; called by muse, mutect2, varscan2
- TP53TG5 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs567269564; called by muse, mutect2, varscan2
- TRABD | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1305918751; called by muse, mutect2, varscan2
- TRAC | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750169372; called by muse, mutect2, varscan2
- TRAF2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs755436517, COSV56040676; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 84/314 reads (27%) | catalogued as rs1470581004, COSV50551177; called by muse, mutect2, varscan2
- TRIM32 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763720824, COSV100525687; called by muse, mutect2, varscan2
- TRIM56 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs199890101, COSV60161217; called by muse, mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 28/103 reads (27%) | catalogued as rs746654944; called by mutect2, pindel, varscan2
- TRPA1 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); catalogued as rs141174965, COSV100085577; called by muse, mutect2, varscan2
- TRPC6 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100723732; called by muse, mutect2, varscan2
- TRPV1 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as rs375905892, COSV51518233; called by muse, mutect2, varscan2
- TSNARE1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs148280960, COSV56182027; called by muse, mutect2
- TTC34 | c.3119G>A p.R1040H | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as rs1027234165; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL13P | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 85/439 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147450804; called by muse, mutect2, varscan2
- TTN | c.100316G>T p.R33439M (on ENST00000591111; = p.R26015M on NM_003319.4) | Missense Mutation (SNP) | VAF 18/244 reads (7%) | PolyPhen possibly damaging (0.634); catalogued as COSV100613890; called by muse, mutect2
- TTN | c.72548G>A p.R24183H (on ENST00000591111; = p.R16759H on NM_003319.4) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | PolyPhen benign (0.007); catalogued as rs376051922; called by muse, mutect2, varscan2
- TTN | c.72323C>T p.A24108V (on ENST00000591111; = p.A16684V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | PolyPhen benign (0.031); catalogued as COSV60190007; called by muse, mutect2, varscan2
- UBXN6 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs375533590; called by muse, mutect2, varscan2
- UNC5C | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV71658775, COSV71660832; called by muse, mutect2, varscan2
- UNC93B1 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs765034492; called by muse, mutect2, varscan2
- UNK | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454325757; called by muse, mutect2, varscan2
- USH1C | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 31/441 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs749924388; called by muse, mutect2
- USO1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752906782; called by muse, mutect2, varscan2
- VIL1 | c.50del p.P17Rfs*73 | Frame Shift Del (DEL) | VAF 62/363 reads (17%) | catalogued as rs1452301630; called by mutect2, pindel, varscan2
- VIL1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs761167420; called by muse, mutect2, varscan2
- VN1R2 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.091); catalogued as rs1394368853; called by muse, mutect2, varscan2
- VNN1 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100907702; called by muse, mutect2, varscan2
- VNN2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs1204346828; called by muse, mutect2, varscan2
- VWDE | c.2100del p.K700Nfs*3 | Frame Shift Del (DEL) | VAF 57/196 reads (29%) | catalogued as rs781003137; called by mutect2, varscan2
- WDR33 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 80/360 reads (22%) | catalogued as rs1297033169, COSV59246969; called by muse, mutect2, varscan2
- WDR87 | c.3173A>C p.E1058A | Missense Mutation (SNP) | VAF 63/387 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs1333893820; called by muse, mutect2, varscan2
- WIPF1 | c.1079del p.P360Rfs*10 | Frame Shift Del (DEL) | VAF 51/245 reads (21%) | catalogued as rs1559146820; called by mutect2, pindel, varscan2
- WIPI1 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs773822577; called by muse, mutect2, varscan2
- WIZ | c.3986G>A p.R1329Q (on ENST00000673675 / NM_001371589.1; = p.R234Q on NM_021241.3) | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs766027386; called by muse, mutect2, varscan2
- WIZ | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568296331; called by muse, mutect2, varscan2
- WIZ | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs567582050; called by muse, varscan2
- WRNIP1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 86/395 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs764102921; called by muse, mutect2, varscan2
- ZBTB8B | c.281A>C p.N94T | Missense Mutation (SNP) | VAF 66/397 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs999335701; called by muse, mutect2, varscan2
- ZC3H7B | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 201/570 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as rs989258774; called by muse, mutect2, varscan2
- ZDHHC12 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199869993, COSV99403583; called by muse, mutect2, varscan2
- ZFAT | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755233371, COSV64741530; called by muse, mutect2, varscan2
- ZFAT | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs747833185, COSV64738099; called by muse, mutect2, varscan2
- ZFP90 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as rs776065123, COSV101238714; called by muse, mutect2, varscan2
- ZFP91 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60158747; called by muse, mutect2, varscan2
- ZFPM2 | c.2674G>A p.G892S | Missense Mutation (SNP) | VAF 89/487 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs776822472, COSV65873600; called by muse, mutect2, varscan2
- ZMIZ1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57892012; called by muse, mutect2
- ZMIZ1 | c.2456C>T p.T819M | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as rs919974519; called by muse, mutect2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 30/194 reads (15%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 25/200 reads (13%) | catalogued as rs751589999; called by mutect2, varscan2
- ZNF16 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs773234511, COSV52764628; called by muse, mutect2, varscan2
- ZNF28 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.221); catalogued as COSV60425778; called by muse, mutect2, varscan2
- ZNF311 | c.970del p.T324Pfs*83 | Frame Shift Del (DEL) | VAF 56/263 reads (21%) | catalogued as COSV65853064; called by mutect2, pindel, varscan2
- ZNF324 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1395574827; called by muse, mutect2, varscan2
- ZNF354A | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59985411; called by muse, mutect2, varscan2
- ZNF496 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.962); catalogued as rs779568946; called by muse, mutect2, varscan2
- ZNF506 | c.345dup p.G116Rfs*3 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs1409120867; called by mutect2, varscan2
- ZNF575 | c.359C>A p.P120Q | Missense Mutation (SNP) | VAF 95/336 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.044); catalogued as rs1198734395, COSV58564643; called by muse, varscan2
- ZNF585A | c.1360C>A p.H454N (on ENST00000292841 / NM_001288800.2; = p.H399N on NM_152655.3) | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.978); catalogued as COSV99493318, COSV99493700; called by muse, mutect2, varscan2
- ZNF611 | c.1369A>G p.K457E | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1213717817, COSV60541283; called by muse, mutect2
- ZNF644 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 120/598 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV61348605; called by muse, mutect2, varscan2
- ZNF776 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as rs778356531, COSV100414236, COSV57815394; called by muse, mutect2, varscan2
- ZNF777 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 82/378 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV56098169; called by muse, mutect2, varscan2
- ZNF835 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 112/506 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs774840356, COSV73379453, COSV73379652; called by muse, varscan2
- ZNF850 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs748702950, COSV101648599; called by muse, mutect2, varscan2
- ZSCAN10 | c.1109C>T p.T370I (on ENST00000252463; = p.T425I on NM_032805.3) | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1374878211; called by muse, mutect2, varscan2
- ZSWIM1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1225498674; called by muse, mutect2, varscan2
- ABCC3 | c.1817T>G p.L606R | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC9 | c.2483A>G p.Q828R | Missense Mutation (SNP) | VAF 103/413 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ABCD3 | c.1470G>A p.W490* | Nonsense Mutation (SNP) | VAF 74/337 reads (22%) | called by muse, mutect2, varscan2
- ABCG8 | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 136/592 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ABTB1 | c.1088G>A p.G363D (on ENST00000232744 / NM_172027.3; = p.G221D on NM_032548.3) | Missense Mutation (SNP) | VAF 70/348 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- AC004593.2 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACOX3 | c.1256T>A p.I419N | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ACTR1A | c.85del p.Q29Rfs*82 | Frame Shift Del (DEL) | VAF 52/249 reads (21%) | called by mutect2, pindel, varscan2
- ADCY1 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ADCY3 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGB | c.246del p.F82Lfs*14 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.8922del p.F2974Lfs*15 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- AFF3 | c.3630G>T p.Q1210H | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGAP1 | c.1399G>T p.G467C | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AK7 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 40/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALDH7A1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 120/362 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ALG10B | c.438dup p.N147* | Frame Shift Ins (INS) | VAF 48/148 reads (32%) | called by mutect2, varscan2
- AMMECR1 | c.220del p.Q74Rfs*89 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- ANAPC5 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- APBB2 | c.1322T>C p.V441A (on ENST00000295974 / NM_001166050.2; = p.V442A on NM_004307.2) | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AQP3 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 97/298 reads (33%) | called by muse, mutect2, varscan2
- AQP6 | c.343del p.A115Lfs*37 | Frame Shift Del (DEL) | VAF 62/172 reads (36%) | called by mutect2, varscan2
- AREL1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ARFGEF1 | c.1376T>C p.L459S | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ARHGEF12 | c.3668G>T p.G1223V | Missense Mutation (SNP) | VAF 57/282 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARID2 | c.4451_4452del p.I1484Sfs*18 | Frame Shift Del (DEL) | VAF 45/169 reads (27%) | called by mutect2, pindel, varscan2
- ARMCX1 | c.1256del p.F419Sfs*16 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | called by mutect2, pindel, varscan2
- ARPIN | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASAP2 | c.2357del p.P786Rfs*25 | Frame Shift Del (DEL) | VAF 27/121 reads (22%) | called by mutect2, pindel, varscan2
- ASTE1 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP13A5 | c.3515C>A p.P1172H | Missense Mutation (SNP) | VAF 132/514 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ATP2A1 | c.1618C>G p.P540A | Missense Mutation (SNP) | VAF 140/510 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V0D1 | c.854del p.P285Lfs*15 | Frame Shift Del (DEL) | VAF 75/366 reads (20%) | called by mutect2, pindel, varscan2
- AUTS2 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- AWAT1 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCOR | c.3462G>T p.E1154D | Missense Mutation (SNP) | VAF 117/435 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BHLHA15 | c.428del p.E143Gfs*? (on ENST00000314018; = p.E143Gfs*80 on NM_177455.4) | Frame Shift Del (DEL) | VAF 66/328 reads (20%) | called by pindel, varscan2
- BMI1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- C11orf86 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C14orf180 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- C15orf65 | c.227del p.F76Sfs*27 | Frame Shift Del (DEL) | VAF 26/214 reads (12%) | called by mutect2, pindel, varscan2
- C5orf52 | c.383del p.K128Sfs*3 | Frame Shift Del (DEL) | VAF 50/178 reads (28%) | called by mutect2, varscan2
- CABP1 | c.668G>A p.R223Q (on ENST00000316803 / NM_001033677.1; = p.R20Q on NM_004276.5) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CACNG3 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CAMSAP3 | c.2690A>G p.D897G | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CARMIL2 | c.678C>A p.D226E | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CASP2 | c.898T>G p.F300V | Missense Mutation (SNP) | VAF 163/644 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CASP9 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 115/486 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC141 | c.1906del p.E636Rfs*5 | Frame Shift Del (DEL) | VAF 23/101 reads (23%) | called by mutect2, pindel, varscan2
- CCDC168 | c.17856del p.K5952Nfs*2 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | called by mutect2, pindel, varscan2
- CCDC168 | c.13675G>A p.E4559K | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CCDC168 | c.5485C>A p.Q1829K | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- CCDC74A | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 78/638 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CCDC8 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 114/514 reads (22%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, varscan2
- CCER2 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCP110 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCR1 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD58 | c.174dup p.Q59Tfs*4 | Frame Shift Ins (INS) | VAF 26/134 reads (19%) | called by mutect2, pindel, varscan2
- CD63 | c.331-2A>G p.X111_splice | Splice Site (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- CDK12 | c.3810del p.G1271Dfs*23 (on ENST00000447079 / NM_016507.4; = p.G1262Dfs*23 on NM_015083.3) | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by pindel, varscan2
- CDV3 | c.272_273del p.K91Rfs*3 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | called by mutect2, pindel, varscan2
- CENPI | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, varscan2
- CEP131 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CEP63 | c.53del p.L18* | Frame Shift Del (DEL) | VAF 50/190 reads (26%) | called by mutect2, pindel, varscan2
- CEP85L | c.73+1G>A p.X25_splice | Splice Site (SNP) | VAF 17/337 reads (5%) | called by muse, mutect2
- CFL1 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CHERP | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHMP1B | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CHRNA4 | c.767T>G p.L256R | Missense Mutation (SNP) | VAF 118/481 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRNB1 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 129/409 reads (32%) | called by muse, mutect2, varscan2
- CLDN11 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 168/796 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLP1 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLPTM1L | c.616del p.T206Pfs*17 | Frame Shift Del (DEL) | VAF 74/318 reads (23%) | called by mutect2, pindel, varscan2
- CLSPN | c.643T>G p.F215V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLTA | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNGA4 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 95/419 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CNOT4 | c.84T>G p.F28L | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); called by muse, mutect2
- CNTRL | c.6747G>T p.K2249N | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL12A1 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- COL5A2 | c.4421T>A p.I1474N | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL9A1 | c.811_812insA p.P271Hfs*3 | Frame Shift Ins (INS) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- COMMD5 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CORO6 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by mutect2, varscan2
- CPE | c.1417A>T p.T473S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CPSF1 | c.3581G>A p.S1194N | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CSRNP3 | c.1259A>C p.E420A | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- CTAGE9 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 150/800 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- CTRB2 | c.53-3dup | Splice Region (INS) | VAF 15/106 reads (14%) | called by mutect2, pindel
- CYP4F8 | c.971C>T p.T324I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DAAM2 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 54/289 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCAF12L2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DDIT3 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- DDX10 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DGCR2 | c.1073_1076del p.F358Sfs*24 | Frame Shift Del (DEL) | VAF 46/240 reads (19%) | called by pindel, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 36/221 reads (16%) | called by mutect2, pindel, varscan2
- DLG2 | c.1275C>G p.H425Q | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DMD | c.10277del p.P3426Lfs*19 | Frame Shift Del (DEL) | VAF 45/241 reads (19%) | called by mutect2, pindel, varscan2
- DMRTC2 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- DNAH11 | c.6680G>A p.G2227D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- DNAH11 | c.13240del p.T4414Qfs*72 | Frame Shift Del (DEL) | VAF 25/159 reads (16%) | called by mutect2, pindel, varscan2
- DNAH6 | c.3216del p.S1073Hfs*8 | Frame Shift Del (DEL) | VAF 46/177 reads (26%) | called by mutect2, pindel, varscan2
- DOK7 | c.568del p.E190Sfs*56 | Frame Shift Del (DEL) | VAF 30/111 reads (27%) | called by mutect2, pindel, varscan2
- DUSP8 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- E2F7 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EEF1D | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EEPD1 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFEMP1 | c.1301dup p.N434Kfs*87 | Frame Shift Ins (INS) | VAF 53/311 reads (17%) | called by mutect2, pindel, varscan2
- EHBP1 | c.1318G>T p.G440W | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EML6 | c.5113G>A p.A1705T | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ENTPD1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- EPG5 | c.1780T>C p.F594L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, varscan2
- EPHA7 | c.1538del p.F513Sfs*23 | Frame Shift Del (DEL) | VAF 19/141 reads (13%) | called by mutect2, pindel, varscan2
- EYS | c.4160G>T p.R1387M | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- FAAP100 | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- FAAP20 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- FAM131A | c.941C>T p.A314V (on ENST00000310585; = p.A345V on NM_144635.5) | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM171A2 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by mutect2, varscan2
- FAM171B | c.525G>A p.W175* | Nonsense Mutation (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- FAM241A | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- FAM241B | c.167G>C p.R56T | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); called by muse, varscan2
- FAM71E2 | c.2342G>A p.G781D | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.05); called by muse, mutect2
- FAM71E2 | c.1674del p.K559Sfs*32 | Frame Shift Del (DEL) | VAF 50/239 reads (21%) | called by mutect2, pindel, varscan2
- FBLL1 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.33); called by muse, mutect2, varscan2
- FBRS | c.1037del p.P346Rfs*39 (on ENST00000287468; = p.P866Rfs*39 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 122/587 reads (21%) | called by mutect2, pindel, varscan2
- FBXO15 | c.696del p.K232Nfs*5 | Frame Shift Del (DEL) | VAF 50/190 reads (26%) | called by mutect2, varscan2
- FBXO46 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGBP | c.8660G>A p.G2887D | Missense Mutation (SNP) | VAF 60/729 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FERMT3 | c.934del p.E312Sfs*16 | Frame Shift Del (DEL) | VAF 39/137 reads (28%) | called by mutect2, pindel, varscan2
- FGA | c.1403C>A p.T468N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FGFR1 | c.2010G>T p.E670D (on ENST00000447712 / NM_023110.3; = p.E668D on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/464 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- FIG4 | c.1137+2T>C p.X379_splice | Splice Site (SNP) | VAF 106/518 reads (20%) | called by muse, mutect2, varscan2
- FILIP1L | c.1104_1106del p.I368del (on ENST00000354552 / NM_182909.3; = p.I128del on NM_014890.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 40/185 reads (22%) | called by mutect2, pindel, varscan2
- FKBP1B | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FMR1 | c.63G>T p.K21N | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FN1 | c.6769A>G p.N2257D (on ENST00000359671 / NM_001365524.2; = p.N2226D on NM_002026.4) | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNIP2 | c.1232dup p.N411Kfs*20 | Frame Shift Ins (INS) | VAF 25/248 reads (10%) | called by mutect2, varscan2
- FOXL3 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXM1 | c.1372A>C p.T458P | Missense Mutation (SNP) | VAF 92/357 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRY | c.1797G>T p.K599N | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FSIP2 | c.2346G>T p.L782F | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.865); called by muse, mutect2
- FSIP2 | c.20722T>C p.*6908Rext*5 | Nonstop Mutation (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- GAR1 | c.430T>G p.F144V | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- GART | c.2123G>T p.R708M | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- GATA1 | c.1073del p.P358Qfs*74 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- GBA3 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 51/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GBP7 | c.519T>A p.F173L | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- GDAP1L1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDF1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- GEMIN5 | c.4010G>T p.R1337M | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GIPR | c.1092G>T p.Q364H | Missense Mutation (SNP) | VAF 139/547 reads (25%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GK3P | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GLA | c.565T>G p.L189V | Missense Mutation (SNP) | VAF 72/364 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLCCI1 | c.411_413del p.R137del | In Frame Del (DEL) | VAF 38/242 reads (16%) | called by pindel, varscan2
- GMDS | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- GPR37 | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 84/376 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPRASP1 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 82/377 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRIK4 | c.2129T>C p.I710T | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GTF2F1 | c.740_743del p.K247Rfs*167 | Frame Shift Del (DEL) | VAF 42/310 reads (14%) | called by pindel, varscan2
- GYS1 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- H2BC9 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 131/580 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by mutect2, varscan2
- HADHB | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- HCN4 | c.2587del p.A863Lfs*9 | Frame Shift Del (DEL) | VAF 33/220 reads (15%) | called by mutect2, pindel, varscan2
- HDAC10 | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 117/361 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HECTD1 | c.7237C>A p.Q2413K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- HGF | c.1604G>A p.C535Y | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HIVEP2 | c.4988C>T p.A1663V | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- HK1 | c.592-1G>T p.X198_splice | Splice Site (SNP) | VAF 134/588 reads (23%) | called by muse, mutect2, varscan2
- HLX | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXC11 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HR | c.616T>C p.F206L | Missense Mutation (SNP) | VAF 85/296 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HRK | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- HSF2BP | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HSP90B1 | c.975del p.V326Lfs*11 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel
- HSPBAP1 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 81/363 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- IAH1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 144/424 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGF1R | c.718A>G p.S240G | Missense Mutation (SNP) | VAF 96/392 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, varscan2
- IGHG4 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 156/624 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.429); called by muse, varscan2
- IGLV3-9 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 204/759 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- IKZF5 | c.15del p.K5Nfs*8 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by mutect2, varscan2
- ILDR2 | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- INPPL1 | c.1322del p.N441Tfs*2 | Frame Shift Del (DEL) | VAF 36/93 reads (39%) | called by mutect2, pindel, varscan2
- INSRR | c.1926G>A p.W642* | Nonsense Mutation (SNP) | VAF 59/252 reads (23%) | called by muse, mutect2, varscan2
- IQANK1 | c.21A>C p.R7S | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IRAK1 | c.739C>A p.L247M | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRF2 | c.529+2T>A p.X177_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | called by muse, varscan2
- ITGB4 | c.3589_3590del p.C1197Rfs*45 | Frame Shift Del (DEL) | VAF 62/304 reads (20%) | called by pindel, varscan2
- JAK1 | c.142del p.L48Sfs*62 | Frame Shift Del (DEL) | VAF 31/177 reads (18%) | called by mutect2, pindel, varscan2
- JAK2 | c.3242T>C p.L1081P | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JPH3 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- JPH3 | c.1740del p.V581Cfs*28 | Frame Shift Del (DEL) | VAF 60/262 reads (23%) | called by mutect2, pindel, varscan2
- KANK4 | c.2972G>T p.R991M | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KCNA1 | c.737A>T p.K246M | Missense Mutation (SNP) | VAF 92/474 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- KCNK7 | c.842del p.G281Vfs*4 | Frame Shift Del (DEL) | VAF 85/340 reads (25%) | called by mutect2, varscan2
- KCTD2 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- KDM5B | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- KDM6A | c.2663C>A p.S888Y | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1210 | c.441A>T p.E147D | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- KIAA1549L | c.766A>G p.T256A (on ENST00000321505; = p.T553A on NM_012194.3) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- KIDINS220 | c.4417del p.L1473Wfs*35 | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | called by mutect2, pindel, varscan2
- KIF20B | c.3395del p.N1132Mfs*11 (on ENST00000371728 / NM_001284259.2; = p.N1092Mfs*11 on NM_016195.4) | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | called by mutect2, pindel, varscan2
- KLC3 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KLHL31 | c.557del p.N186Mfs*24 | Frame Shift Del (DEL) | VAF 49/272 reads (18%) | called by mutect2, pindel, varscan2
- KLHL34 | c.1660T>G p.L554V | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KLRG1 | c.175A>T p.I59F | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KMT2A | c.1660del p.Q554Sfs*13 | Frame Shift Del (DEL) | VAF 62/245 reads (25%) | called by mutect2, varscan2
- KRT23 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KRTAP5-10 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 93/403 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- LARS1 | c.2842C>T p.Q948* (on ENST00000394434 / NM_020117.11; = p.Q921* on NM_016460.3) | Nonsense Mutation (SNP) | VAF 43/177 reads (24%) | called by muse, mutect2, varscan2
- LCA5L | c.350del p.K117Sfs*15 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- LCN12 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LGI4 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LIME1 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- LMF2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LMNA | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 75/339 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- LRIF1 | c.411T>A p.S137R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP1B | c.13708C>T p.Q4570* | Nonsense Mutation (SNP) | VAF 20/125 reads (16%) | called by muse, mutect2, varscan2
- LRRC71 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- LRRTM1 | c.724A>G p.R242G | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.779G>T p.R260M | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- MADD | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 137/565 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MAF | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 82/336 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEA6 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEL2 | c.2587del p.Q863Rfs*41 | Frame Shift Del (DEL) | VAF 52/230 reads (23%) | called by mutect2, pindel, varscan2
- MAMDC2 | c.1766T>C p.M589T | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAP3K20 | c.2300dup p.W768Lfs*20 | Frame Shift Ins (INS) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- MAP3K21 | c.1984A>G p.I662V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.044); called by muse, mutect2
- MAPK8IP1 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MAPT | c.83dup p.Y29Lfs*10 | Frame Shift Ins (INS) | VAF 66/283 reads (23%) | called by mutect2, varscan2
- MARK1 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 52/488 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
710 further variants in this file (247 protein-altering or splice-affecting, 275 silent, 188 other) are not listed here.
